FM case AD7896 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/955ebc26-2090-46d9-85b5-5944870063b2

Male, 51.7 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the overlapping lesion of nasopharynx; metastasis biopsied or resected from the head, face or neck. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
